Somatic mutation profile of tumor specimen ALCH-B3AW-TTP1-A (aliquot ALCH-B3AW-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3AW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.3 years (24,204 days).
Specimen ALCH-B3AW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee08b0bc-294e-4bdf-82fe-4ccd6b884a5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3AW-NB1-A (Blood Derived Normal), aliquot ALCH-B3AW-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a06f3aa6-b433-4595-92c9-27927f61b363

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 5 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 5, Intron 3, 3'UTR 2, RNA 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 88/578 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- FAM83B | c.1571A>G p.D524G | Missense Mutation (SNP) | VAF 16/417 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1220017228; called by muse, mutect2
- PDE1C | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 113/718 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.142); catalogued as rs776200538; called by muse, mutect2, varscan2
- PRDM13 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 73/415 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs778690412; called by muse, mutect2, varscan2
- RBM10 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 31/244 reads (13%) | catalogued as COSV61310856; called by muse, mutect2, varscan2
- SLC16A13 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs902826626; called by muse, mutect2
- SLITRK3 | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs748456407, COSV53846864, COSV53847822; called by muse, mutect2, varscan2
- SPANXN1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs143004346, COSV65122800, COSV65123130; called by muse, mutect2
- ADAMTS1 | c.2716G>A p.D906N | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADAMTS1 | c.2647G>A p.D883N | Missense Mutation (SNP) | VAF 66/557 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- AMOTL1 | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ANLN | c.393C>G p.N131K | Missense Mutation (SNP) | VAF 20/540 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.024); called by muse, mutect2
- ASB16 | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BYSL | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- CEP250 | c.948+7G>T | Splice Region (SNP) | VAF 20/304 reads (7%) | called by muse, mutect2
- CNNM1 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYSLTR2 | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 17/496 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- DOK7 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, varscan2
- FOXRED2 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 56/439 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAO1 | c.102A>C p.E34D | Missense Mutation (SNP) | VAF 16/353 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.158); called by muse, mutect2
- IGHV3-33 | c.143T>A p.F48Y | Missense Mutation (SNP) | VAF 62/604 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- IQSEC2 | c.3303G>A p.M1101I (on ENST00000642864 / NM_001111125.3; = p.M896I on NM_015075.2) | Missense Mutation (SNP) | VAF 56/310 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IVNS1ABP | c.1793A>C p.N598T | Missense Mutation (SNP) | VAF 30/1100 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIF1A | c.4940C>G p.P1647R (on ENST00000320389 / NM_001379639.1; = p.P1639R on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- LAMA1 | c.2870G>A p.G957D | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPC4L | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 20/495 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- RGPD4 | c.5012G>A p.G1671D | Missense Mutation (SNP) | VAF 128/1009 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RIMS1 | c.4990C>A p.L1664M | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SIDT1 | c.1171C>G p.P391A | Missense Mutation (SNP) | VAF 44/376 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNR | c.2998G>A p.D1000N | Missense Mutation (SNP) | VAF 122/448 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, varscan2
- TTC3 | c.5638G>A p.G1880R | Missense Mutation (SNP) | VAF 128/788 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- TTN | c.10681A>T p.I3561F (on ENST00000591111; = p.I3515F on NM_003319.4) | Missense Mutation (SNP) | VAF 43/1192 reads (4%) | called by muse, mutect2
- VWA5B1 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- WDR72 | c.230A>G p.Q77R | Missense Mutation (SNP) | VAF 30/744 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZHX1 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 49/418 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- GJB7 | c.216C>G p.S72= | Silent (SNP) | VAF 57/325 reads (18%) | called by muse, mutect2, varscan2
- ITGAM | c.1908A>G p.V636= (on ENST00000648685 / NM_001145808.2; = p.V635= on NM_000632.4) | Silent (SNP) | VAF 38/260 reads (15%) | called by muse, mutect2, varscan2
- LRRC7 | c.3357G>T p.P1119= (on ENST00000651989 / NM_001370785.2; = p.P1086= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/363 reads (7%) | catalogued as COSV99224841; called by muse, mutect2
- PSME4 | c.4263T>C p.Y1421= | Silent (SNP) | VAF 94/485 reads (19%) | catalogued as rs200012441; called by muse, mutect2, varscan2
- ZNF407 | c.3741A>G p.R1247= | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- ADAM1A | n.1620T>C | RNA (SNP) | VAF 35/262 reads (13%) | called by muse, mutect2, varscan2
- BMP7 | c.611+2275C>T | Intron (SNP) | VAF 32/249 reads (13%) | catalogued as rs1001622596; called by muse, varscan2
- CHRNA4 | c.*168C>T | 3'UTR (SNP) | VAF 177/424 reads (42%) | catalogued as rs954106130; called by muse, mutect2, varscan2
- LINC02740 | n.257G>T | RNA (SNP) | VAF 59/391 reads (15%) | catalogued as rs186650712; called by muse, mutect2, varscan2
- NOP58 | c.175+249T>G | Intron (SNP) | VAF 118/769 reads (15%) | catalogued as rs1273661105; called by muse, mutect2, varscan2
- NUP155 | c.*30G>C | 3'UTR (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
- PDGFRA | c.2323+1121G>A | Intron (SNP) | VAF 51/378 reads (13%) | catalogued as rs866730854; called by muse, mutect2, varscan2
